Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1DM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1DM-01A (Primary Tumor).

[page 1 of 3]
100-0-3

Adenocarcinoma, Endometrioid, NOS 8:
Site Code: Endometrium C54.1

TSS Name/##:

1/1:

Specimens Submitted:

- 1: SP: Biopsy of right ovary
- 2: SP: Right para-aortic lymph nodes
- 3: SP: Right common iliac lymph nodes
- 4: SP: Left para-aortic lymph nodes
- 5: SP: Left common iliac lymph nodes
- 6: SP: Left external iliac lymph nodes
- 7: SP: Distal left external iliac lymph nodes
- 8: SP: Left hypogastric lymph nodes
- 9: SP: Left obturator lymph nodes
- 10: SP: Right external iliac lymph nodes
- 11: SP: Distal right external iliac lymph nodes
- 12: SP: Right hypogastric lymph nodes
- 13: SP: Right obturator lymph nodes
- 14: SP: Uterus, cervix, bilateral fallopian tubes and ovaries

DIAGNOSIS:

- 1) OVARY, RIGHT, BIOPSY:
- BENIGN OVARIAN TISSUE.
- 2) LYMPH NODE, RIGHT PARA-AORTIC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LYMPH NODES, RIGHT COMMON ILIAC, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 4) LYMPH NODES, LEFT PARA-AORTIC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODE, LEFT COMMON ILIAC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 7) LYMPH NODES, DISTAL LEFT EXTERNAL ILIAC, EXCISION:

** Continued on next page **

UUID: E25BA7AD-SC24-4953-B9C3-7509AE6E9F4C

[page 2 of 3]
TSS Name/##: |

- FOUR BENIGN LYMPH NODES (0/4).

8) LYMPH NODE, LEFT HYPOGASTRIC, EXCISION:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE.

9) LYMPH NODES, . LEFT OBTURATOR, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

10) LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

11) LYMPH NODES, DISTAL RIGHT EXTERNAL ILIAC, EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).

12) LYMPH NODE, RIGHT HYPOGASTRIC, EXCISION:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE.

13) LYMPH NODES, RIGHT OBTURATOR, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

14) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND
BILATERAL SALPINGO- OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE 1.
- THE TUMOR INVADES LESS THAN HALF OF THE MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 3 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION
IS 13 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ADENOMYOSIS.
- THE RIGHT OVARY SHOWS ENDOMETRIOSIS.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- PENDING IMMUNOHISTOCHEMICAL STUDY FOR DNA MISMATCH REPAIR GENE
EXPRESSION.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

[page 3 of 3]
TSS Name/##:

Page 7 of 8

Procedures/Addenda:
Addendum

Addendum Diagnosis

ADDENDUM

PART #14
SITE: UTERUS

RESULTS OF IMMUNOHISTOCHEMICAL STAINING FOR DNA MISMATCH REPAIR PROTEINS ARE
AS FOLLOWS:

MLH1:	STAINING ABSENT IN TUMOR
MSH2:	STAINING PRESENT IN TUMOR
MSH6:	STAINING PRESENT IN TUMOR
PMS2:	STAINING ABSENT IN TUMOR

CONCLUSION:
IMMUNOHISTOCHEMICAL STUDY FOR DNA MISMATCH REPAIR GENE EXPRESSION
DEMONSTRATE THAT THE
TUMOR CELLS HAVE LOSS OF EXPRESSION OF MLH1 AND PMS2 AND RETAINED THE
EXPRESSION OF MSH2
AND MSH6. DR. [REDACTED] HAS REVIEWED THESE SLIDES AND CONCURS.

Source: NCI Genomic Data Commons file f865784c-b728-4375-9801-7084cbce8232 (TCGA-AP-A1DM.E25BA7AD-5C24-4953-B9C3-7509AE6E9F4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).